Somatic mutation profile of tumor specimen C3N-01522-03 (aliquot CPT0077130009) from CPTAC case C3N-01522, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.4 years (29,350 days).
Specimen C3N-01522-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30bee849-e2a4-4984-86a4-aa23876465a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01522-71 (Blood Derived Normal), aliquot CPT0077230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b7a2d53-3ba3-4a0d-9e5e-667f3b538741

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 6, Intron 3, 3'UTR 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3203C>T p.S1068L | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); catalogued as CD160909, CM023010, COSV57330367, COSV57359180; called by muse, mutect2
- BCLAF1 | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as rs147719127; called by muse, mutect2
- CTAGE1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 11/248 reads (4%) | catalogued as COSV101194675; called by muse, mutect2
- GBP3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV52519257; called by muse, mutect2
- KDM5C | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 28/232 reads (12%) | catalogued as CM061210, COSV64763470; called by muse, mutect2, varscan2
- LRP1 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 36/721 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs769851229, COSV54507646; ClinVar: uncertain significance; called by muse, mutect2
- MAGEC3 | c.1813A>G p.M605V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs200784001; called by muse, mutect2, varscan2
- MROH2A | c.2306C>G p.P769R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1025990760; called by muse, mutect2
- OR5J2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 12/175 reads (7%) | catalogued as COSV100399225; called by muse, mutect2
- PITPNM3 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 27/561 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs373601000; called by muse, mutect2
- PLA2G7 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs928438839; called by muse, mutect2
- SLITRK6 | c.2135G>A p.S712N | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1438568169; called by muse, mutect2
- SPTBN2 | c.6343G>A p.G2115S | Missense Mutation (SNP) | VAF 35/749 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs200435710; called by muse, mutect2
- TMEM108 | c.166A>G p.S56G | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs1303009645; called by muse, mutect2
- ABCC3 | c.1635+1G>A p.X545_splice | Splice Site (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
- CHD6 | c.2629T>C p.F877L | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CILP2 | c.978G>T p.W326C | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM227A | c.1129C>A p.H377N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- KLHL30 | c.1587C>A p.Y529* | Nonsense Mutation (SNP) | VAF 25/546 reads (5%) | called by muse, mutect2
- LMO7 | c.4657C>G p.P1553A (on ENST00000357063; = p.P1234A on NM_005358.5) | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MPND | c.1048A>G p.S350G | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTRF1 | c.815T>C p.M272T | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, mutect2
- NSD1 | c.2204C>A p.A735E | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- OR52H1 | c.423G>C p.K141N (on ENST00000322653; = p.K147N on NM_001005289.1) | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.131); called by muse, mutect2
- PAFAH2 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PCED1A | c.821C>G p.P274R | Missense Mutation (SNP) | VAF 16/297 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRR33 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
- RIC8A | c.1065+2T>C p.X355_splice | Splice Site (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- ROCK2 | c.3176A>C p.K1059T | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- SLC4A8 | c.2054G>T p.G685V | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- SLCO1C1 | c.1888T>G p.C630G | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TDRD12 | c.296A>T p.K99M | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- TRPV5 | c.1592T>A p.F531Y | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.761); called by muse, mutect2
- ATP11B | c.1230T>C p.G410= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- DCUN1D2 | c.291T>A p.P97= | Silent (SNP) | VAF 21/314 reads (7%) | called by muse, mutect2
- FNIP2 | c.1905G>A p.G635= | Silent (SNP) | VAF 17/216 reads (8%) | called by muse, mutect2
- HYAL4 | c.1236C>T p.D412= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as rs201879421, COSV56139321; called by muse, mutect2
- IFT172 | c.4383G>A p.Q1461= | Silent (SNP) | VAF 20/243 reads (8%) | catalogued as COSV53137617; called by muse, mutect2
- LIPA | c.171T>C p.D57= | Silent (SNP) | VAF 25/279 reads (9%) | called by muse, mutect2
- NCCRP1 | c.54G>A p.G18= | Silent (SNP) | VAF 32/600 reads (5%) | catalogued as rs753673551; called by muse, mutect2
- PRR14 | c.1272A>G p.P424= | Silent (SNP) | VAF 19/269 reads (7%) | called by muse, mutect2
- RAET1E | c.198T>C p.S66= | Silent (SNP) | VAF 24/289 reads (8%) | called by muse, mutect2
- TTN | c.48192A>G p.V16064= (on ENST00000591111; = p.V8640= on NM_003319.4) | Silent (SNP) | VAF 41/512 reads (8%) | catalogued as rs1182402471; called by muse, mutect2
- ZNF343 | c.1621A>C p.R541= | Silent (SNP) | VAF 34/279 reads (12%) | catalogued as rs769462325; called by muse, mutect2, varscan2
- COLEC11 | c.*67A>T | 3'UTR (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- CSNK1D | c.737-51T>A | Intron (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- MTHFR | c.475+9C>A | Intron (SNP) | VAF 29/320 reads (9%) | called by muse, mutect2
- PDE4DIP | c.*52A>T | 3'UTR (SNP) | VAF 27/456 reads (6%) | called by muse, mutect2
- PDE6B | c.1060-39G>A | Intron (SNP) | VAF 12/182 reads (7%) | catalogued as rs369121532; called by muse, mutect2
- UBR7 | c.*161A>T | 3'UTR (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
